Somatic mutation profile of tumor specimen TCGA-DX-A3U7-01A (aliquot TCGA-DX-A3U7-01A-11D-A29N-09) from TCGA case TCGA-DX-A3U7, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 67.7 years (24,723 days).
Specimen TCGA-DX-A3U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 031f22d5-6e29-434a-8650-e40dbde4cf91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3U7-10A (Blood Derived Normal), aliquot TCGA-DX-A3U7-10A-01D-A29N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/720d292b-736d-4eeb-b699-e9b2ee97b67b

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 22, Silent 7, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS17 | c.2954C>T p.S985L | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1353227852; called by muse, mutect2, varscan2
- CD48 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.448); catalogued as COSV63567059; called by muse, mutect2, varscan2
- CGB8 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.55); PolyPhen benign (0.148); catalogued as COSV100031890; called by muse, mutect2, varscan2
- COLEC12 | c.120C>G p.I40M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV101231910; called by muse, mutect2, varscan2
- DERL1 | c.532C>G p.L178V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as COSV99418748; called by muse, mutect2, varscan2
- FRG2B | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV101423488; called by muse, mutect2, varscan2
- KCNH8 | c.2504G>A p.R835Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs757153750, COSV100110320; called by muse, mutect2, varscan2
- OR7E24 | c.383T>A p.M128K | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV71702219; called by muse, mutect2, varscan2
- PEX7 | c.337G>C p.E113Q | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59252129; called by muse, mutect2, varscan2
- RET | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs373594744, COSV104412311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RPGRIP1 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs1055644990; called by muse, mutect2, varscan2
- SLC8A2 | c.1907C>G p.T636R | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as COSV99370154; called by muse, mutect2, varscan2
- TMCO6 | c.1370C>G p.A457G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.179); catalogued as COSV52799605; called by muse, varscan2
- C19orf57 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- CIAO1 | c.265_288+1del | Frame Shift Del (DEL) | VAF 14/88 reads (16%) | called by mutect2, pindel, varscan2
- F13A1 | c.1604A>T p.K535M | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FAT4 | c.5452G>T p.D1818Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FSTL5 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GLYATL1 | c.346G>T p.V116L (on ENST00000317391 / NM_001354699.1; = p.V147L on NM_080661.4) | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IRGC | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- RYR1 | c.13595C>T p.P4532L | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2
- UNC13C | c.3320C>T p.T1107I | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- USP24 | c.7728dup p.E2577Rfs*7 | Frame Shift Ins (INS) | VAF 20/82 reads (24%) | called by mutect2, pindel, varscan2
- VPS13C | c.2885T>G p.I962S (on ENST00000644861 / NM_020821.3; = p.I919S on NM_017684.5) | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ZNF106 | c.4708C>A p.H1570N | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF215 | c.1065T>A p.Y355* | Nonsense Mutation (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- CCDC157 | c.1245G>A p.R415= | Silent (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- COL17A1 | c.2922T>A p.L974= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- DCBLD2 | c.1200G>A p.V400= | Silent (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- DYNC2LI1 | c.676C>T p.L226= | Silent (SNP) | VAF 50/75 reads (67%) | catalogued as rs373318313; called by muse, mutect2, varscan2
- MCCC1 | c.561A>T p.S187= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- SCGB1D4 | c.33G>C p.S11= | Silent (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- STXBP3 | c.28C>T p.L10= | Silent (SNP) | VAF 16/29 reads (55%) | called by muse, mutect2
